Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-6222, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-6222-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Consultation Report

Specimen(s) Received

1. Nck: Right neck Level I-A
2. Nck: Right neck Level I-B
3. Nck: Right neck Level II-A
4. Nck: Right neck Level II-B
5. Nck: Right neck Level III
6. Nck: Right neck Level IV
7. Nck: Right neck Level V
8. Neck: Right hemiglossectomy, stitch marks anterior
9. Neck: dorsal tongue margin
10. Neck: deep tongue margin
11. Neck: tongue base margin
12. Neck: floor of mouth margin
13. Neck: right sublingual gland -
14. Lymph node: right neck level IV lymph nodes,
15. Lymph node: right neck level V lymph node,

Diagnosis

1. Right neck level IA.
Five lymph nodes negative for tumor (0/5).
2. Right neck level IB.
Six lymph nodes negative for tumor (0/6).
3. Right neck level IIA.
One of five lymph nodes positive for metastatic squamous cell carcinoma (1/5).
- a. The involved lymph node measures 1.5 cm.
- b. No extracapsular extension.Submandibular gland with no pathologic changes.
4. Right neck level IIB.
Seven lymph nodes negative for tumor (0/7).
5. Right neck level III.

[page 2 of 5]
One of two lymph nodes positive for metastatic squamous cell carcinoma (1/2).

- a. The involved lymph node measures 1.8 cm.
- b. Extensive extracapsular extension present.

6. Right neck level IV.

Fifteen lymph nodes negative for tumor (0/15).

7. Right neck level V.

Eighteen lymph nodes negative for tumor (0/18).

8. Oral cavity; tongue; right hemiglossectomy.

Squamous cell carcinoma, moderately differentiated.

- a. Maximum tumor dimension 3.6 cm.
- b. Tumor thickness 2.2 cm.
- c. No perineural invasion.
- d. No lymphovascular invasion.
- e. Margins negative for tumor.

9. Dorsal tongue margin.

Negative for tumor.

10. Deep tongue margin.

Negative for tumor.

11. Tongue base margin.

Negative for tumor.

12. Floor of mouth margin.

Negative for tumor.

13. Right sublingual gland.

Sublingual gland with no pathologic changes.

12. Right neck level IV.

One lymph node negative for tumor (0/1).

13. Right neck level V.

Seven lymph nodes negative for tumor (0/7).

Synoptic Data

Specimen Type:	Resection:right hemiglossectomy
Tumor Site:	Tongue
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 3.6 cm Tumor thickness: 2.2 cm
Histologic Grade:	G2: Moderately differentiated
Pathologic Staging (pTNM):	pT2: Tumor of lip or oral cavity more than 2 cm but not more than 4 cm in greatest dimension pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension for all aerodigestive sites except nasopharynx pMX: Distant metastasis cannot be assessed

[page 3 of 5]
verified by:

Electronically

Clinical History

Oral CA

Gross Description

1. The specimen is labeled with the patient's name and as "NCK: Right neck level I-A". It consists of a piece of fibroadipose tissue that measures 3.5 x 3.3 x 1.0 cm and contains multiple lymph nodes that range from 0.4 to 0.7 cm. Representative sections are submitted.

1A two lymph nodes

1B three lymph nodes

2. The specimen is labeled with the patient's name and as "NCK: Right neck level I-B". It consists of a piece of fibroadipose tissue that measures 5.5 x 5.3 x 2.0 cm and contains multiple lymph nodes that range from 0.3 to 2.0 cm. The submandibular gland measures 4.5 x 3.3 x 1.6 cm and is grossly unremarkable. Representative sections are submitted.

2A submandibular gland

2B one bisected lymph node

2C-2D two lymph nodes per block

2E three lymph nodes

3. The specimen is labeled with the patient's name and as "NCK: Right neck level II-A". It consists of a piece of fibroadipose tissue that measures 4.5 x 3.7 x 1.5 cm and contains multiple lymph nodes that range from 0.3 to 2.2 cm. Representative sections are submitted.

3A-3C one bisected lymph node per block

3D two lymph nodes

4. The specimen is labeled with the patient's name and as "NCK: Right neck level II-B". It consists of a piece of fibroadipose tissue that measures 4.0 x 2.7 x 1.0 cm and contains multiple lymph nodes that range from 0.2 to 0.6 cm. Representative sections are submitted.

4A-4B two lymph nodes per block

4C four lymph nodes

5. The specimen is labeled with the patient's name and as "NCK: Right neck level III". It consists of a piece of fibroadipose tissue that measures 6.8 x 4.0 x 1.8 cm and contains two lymph nodes that measure 2.0 and 3.2 cm in maximum dimension. The larger lymph node has a firm, tan parenchyma. Representative sections are submitted.

5A-5F larger lymph node, serially sectioned

5G smaller lymph node, bisected

6. The specimen is labeled with the patient's name and as "NCK: Right neck level IV". It consists of a piece of fibroadipose tissue that measures 5.3 x 2.5 x 1.1 cm and contains multiple lymph nodes that range from 0.2 to 0.9 cm. The specimen is received with a separate 4.2 x 0.9 x 0.6 cm piece of grossly unremarkable muscle. Representative sections are submitted.

6A-6B three lymph nodes per block

6C-6E four lymph nodes per block

7. The specimen is labeled with the patient's name and as "NCK: Right neck level V". It consists of a piece of fibroadipose tissue that measures 8.6 x 5.7 x 1.5 cm and contains multiple lymph nodes that range from 0.4 to 0.9 cm. Representative sections are submitted.

[page 4 of 5]
7A-7B two lymph nodes per block
7C-7G three lymph nodes per block

8. The specimen is labeled the patient's name and as "neck: Right hemiglossectomy, stitch marks anterior QS". It consists of a portion of right tongue measuring 5.5 cm AP x 3.5 cm SI x 3.0 cm ML. There is anterior suture orientation. At the inferolateral specimen aspect, there is a 1.8 cm AP x 0.5 cm ML portion of floor of mouth. There is a firm, pale tumor involving the lateral tongue. The tumor measures 3.6 cm AP x 2.2 cm SI x 1.3 cm ML. The tumor is irregularly shaped. It is located at 0.4 cm from the lateral floor of mouth margin, 0.4 cm from the medial margin, 1.2 cm from the inferior margin, 0.6 cm from the anterior margin, and 1.0 cm from the posterior margin. The remaining tongue mucosa shows white plaques on the postero-dorsal surface of the tongue, medially adjacent to the tumor. These plaques measure 1.3 x 0.7 cm in aggregate. The surgical margins are painted with silver nitrate; superior margins are overcoated with green dye. The tumor (three pieces) and normal tissue (two pieces) are sampled for tissue banking. Representative sections are submitted.

8A tumor, with anterior margin, perpendicular section

8B posterior margin, perpendicular section

8C tumor involving dorsal surface of tongue, perpendicular section

8D inferior margin, perpendicular section

8E tumor, with medial margin, perpendicular section

8F tumor involving the lateral surface of tongue, perpendicular section

8G tumor, with lateral floor of mouth margin, perpendicular section

8H tumor

8I mucosal plaques on postero-dorsal tongue

9. The specimen is labeled with the patient's name and as "neck: Dorsal tongue margin [REDACTED]". It consists of a fragment of tissue measuring 5.5 x 0.8 cm. The specimen is submitted in toto for frozen section.

9A frozen section control

10. The specimen is labeled with the patient's name and as "neck: Deep tongue margin [REDACTED]". It consists of a fragment of tissue measuring 1.4 x 1.0 x 0.3 cm. The specimen is submitted in toto for frozen section.

10A frozen section control

11. The specimen is labeled with the patient's name and as "neck: Tongue base margin [REDACTED]". It consists of a fragment of tissue measuring 1.2 x 0.6 x 0.3 cm. The specimen is submitted in toto for frozen section.

11A frozen section control

12. The specimen is labeled with the patient's name and as "neck: Floor of mouth margin [REDACTED]". It consists of two fragments of tissue measuring 0.7 x 0.4 x 0.3 and 1.0 x 0.6 x 0.4 cm. The specimen is submitted in toto for frozen section.

12A frozen section control

13. The specimen is labeled with the patient's name and as "neck: Right sublingual gland -- [REDACTED]". It consists of a 2.3 x 1.5 x 0.8 cm irregular piece of unoriented soft tissue, which is painted with silver nitrate.

13A-13B serially sectioned and submitted in toto

14. The specimen labeled with the patient's name and as "lymph node: Right neck level IV lymph nodes, [REDACTED] consists of a 1.3 x 0.8 x 0.7 cm lymph node.

14A bisected and submitted in toto

15. The specimen is labeled with the patient's name and as "lymph node: Right neck level V lymph node [REDACTED]". It consists of a piece of fibroadipose tissue that measures 4.2 x 2.3 x 1.3 cm

[page 5 of 5]
and contains multiple lymph nodes that range from 0.2 to 2.0 cm. Representative sections are submitted.

15A one bisected lymph node

15B three lymph nodes

15C four lymph nodes

██████████

Quick Section Diagnosis

9A Dorsal tongue margin:

- Negative for malignancy

10A Deep tongue margin:

- Negative for malignancy

11A Tongue base margin:

- Negative for malignancy

12A Floor of mouth margin:

- Negative for malignancy

(reported ██████)

██████████

██████████

██████████

Source: NCI Genomic Data Commons file ecbace58-3385-4d15-a08a-1d1ce92e626c (TCGA-CQ-6222.F788DF0B-7EAD-4B0F-89FE-E9650A99072A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).